Somatic mutation profile of tumor specimen C3N-01180-01 (aliquot CPT0088970009) from CPTAC case C3N-01180, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.3 years (18,748 days).
Specimen C3N-01180-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dd94a25-e473-49ae-bdbb-a5bce4d6ac65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01180-31 (Blood Derived Normal), aliquot CPT0089010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97a0f1a2-42c4-4791-ae98-e7bc5eba601c

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Silent 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO2 | c.2324T>G p.M775R | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV53442908; called by muse, mutect2
- FANCM | c.6061_6063del p.E2021del | In Frame Del (DEL) | VAF 42/121 reads (35%) | catalogued as rs770012987; called by pindel, varscan2
- CLPTM1L | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LMNB2 | c.1711-2A>G p.X571_splice | Splice Site (SNP) | VAF 34/548 reads (6%) | called by muse, mutect2
- MINDY4 | c.1707G>A p.L569= | Silent (SNP) | VAF 17/259 reads (7%) | called by muse, mutect2
- NTRK3 | c.2295C>A p.T765= (on ENST00000360948 / NM_001012338.2; = p.T751= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/451 reads (7%) | called by muse, mutect2
- DIABLO | c.305-1139A>C | Intron (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- LDLR | c.67+1141C>G | Intron (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- NRXN1 | c.3365-109809C>A | Intron (SNP) | VAF 15/450 reads (3%) | called by muse, mutect2
